Somatic mutation profile of tumor specimen ALCH-B1VT-TTP1-A (aliquot ALCH-B1VT-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1VT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 59.1 years (21,576 days).
Specimen ALCH-B1VT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97125dfa-9bf3-4bfd-8ee2-a5ddd418c767.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VT-NB1-A (Blood Derived Normal), aliquot ALCH-B1VT-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/add0ae6b-307f-4648-ad55-211caab5b33a

The open-access MAF lists 89 somatic variants for this specimen: 56 protein-altering or splice-affecting, 28 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 28, Nonsense Mutation 6, RNA 3, Intron 2, Frame Shift Del 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs886039497; called by muse, mutect2
- ACRBP | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs760545577; called by mutect2, varscan2
- COL3A1 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 31/500 reads (6%) | catalogued as COSV58593877; called by muse, mutect2
- EPB41L1 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52442227; called by muse, mutect2
- FAM135B | c.2929G>T p.E977* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV52704157, COSV52733487; called by muse, mutect2, varscan2
- FUZ | c.1033+3C>G | Splice Region (SNP) | VAF 22/280 reads (8%) | catalogued as rs534754038; called by muse, mutect2
- MIA2 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV99698313; called by muse, mutect2, varscan2
- MUC12 | c.15926C>T p.A5309V (on ENST00000379442; = p.A5166V on NM_001164462.1) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); catalogued as rs971900835, COSV59331121; called by muse, mutect2
- OR4C46 | c.285C>A p.C95* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as COSV60220556; called by muse, mutect2, varscan2
- OR4C6 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs1237065523, COSV58603612; called by muse, mutect2
- RBBP9 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs376756380; called by muse, mutect2
- SCN4A | c.4783G>A p.A1595T | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs761947899, COSV71127375; called by muse, mutect2
- SLC18A3 | c.1145C>A p.P382Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as COSV60321307; called by muse, mutect2, varscan2
- THOC1 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs947264802, COSV55274051; called by muse, mutect2
- TSN | c.685T>C p.*229Qext*26 | Nonstop Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs1281506629; called by mutect2, varscan2
- ADGRL3 | c.818G>C p.R273T (on ENST00000506720 / NM_001322402.2; = p.R205T on NM_015236.6) | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2
- ARMH3 | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.147); called by muse, mutect2
- ASPM | c.7357C>G p.Q2453E | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.042); called by muse, mutect2
- CACNA1H | c.2206C>T p.H736Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.255); called by muse, mutect2
- CSMD1 | c.4702C>G p.P1568A (on ENST00000520002; = p.P1567A on NM_033225.6) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DROSHA | c.2492A>T p.K831M | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DST | c.18260A>C p.Q6087P (on ENST00000361203 / NM_001374722.1; = p.Q3784P on NM_015548.5) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ERVMER34-1 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2
- FAM178B | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- FGR | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- G6PD | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KAT6A | c.1523G>C p.C508S | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2
- KCNB2 | c.1625T>A p.M542K | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.253); called by muse, mutect2
- KCNH7 | c.3227C>A p.A1076E | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- KMT2B | c.2034G>T p.E678D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KRT8 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2
- L1CAM | c.355A>G p.K119E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LCT | c.1371G>T p.W457C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYH6 | c.2551A>G p.M851V | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- OR10C1 | c.485C>G p.P162R (on ENST00000622521; = p.P160R on NM_013941.3) | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.053); called by muse, mutect2
- OR2G6 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 9/303 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5V1 | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH11X | c.2324C>A p.S775* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- PRUNE2 | c.6298C>T p.Q2100* | Nonsense Mutation (SNP) | VAF 11/127 reads (9%) | called by muse, mutect2
- RFX4 | c.1649A>G p.Y550C (on ENST00000392842 / NM_213594.3; = p.Y456C on NM_032491.6) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- RIPK4 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO4 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.021); called by muse, mutect2
- RSPH4A | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- RTP4 | c.478G>C p.G160R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC11A1 | c.1262T>G p.L421R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SPTA1 | c.2606A>C p.D869A | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2
- TBC1D3B | c.1129C>A p.R377S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TDRD1 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEAD2 | c.1043G>T p.C348F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- TRIB2 | c.955del p.Y319Mfs*57 | Frame Shift Del (DEL) | VAF 13/131 reads (10%) | called by mutect2, pindel, varscan2
- TTN | c.81592G>C p.V27198L (on ENST00000591111; = p.V19774L on NM_003319.4) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | PolyPhen benign (0.011); called by muse, mutect2
- TUBGCP2 | c.2180C>A p.T727K | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2
- TUBGCP4 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, varscan2
- ZNF804A | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZP3 | c.597G>T p.Q199H (on ENST00000394857 / NM_001110354.2; = p.Q148H on NM_007155.6) | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ABCB5 | c.1219C>T p.L407= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2
- ACSM5 | c.333C>T p.G111= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2, varscan2
- BPIFC | c.1125T>G p.V375= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- CSMD1 | c.549G>T p.L183= | Silent (SNP) | VAF 17/226 reads (8%) | catalogued as rs1251695216; called by muse, mutect2
- CYTIP | c.907C>A p.R303= | Silent (SNP) | VAF 11/216 reads (5%) | catalogued as COSV51634703; called by muse, mutect2
- DCLK2 | c.588C>A p.P196= | Silent (SNP) | VAF 35/352 reads (10%) | called by muse, mutect2, varscan2
- FAT3 | c.2067T>C p.A689= | Silent (SNP) | VAF 13/210 reads (6%) | catalogued as rs1385553024; called by muse, mutect2
- FNDC1 | c.1548T>C p.N516= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs941443121; called by muse, mutect2
- FSIP2 | c.2850A>T p.V950= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- ITIH5 | c.18G>C p.G6= | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- MYT1L | c.96C>A p.P32= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- NUP214 | c.4446C>T p.T1482= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs1288716390; called by muse, mutect2, varscan2
- OR1S1 | c.448C>A p.R150= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV58706093, COSV58708726; called by muse, mutect2, varscan2
- OR2L5 | c.888G>T p.V296= | Silent (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- OR2T4 | c.837G>T p.V279= | Silent (SNP) | VAF 26/402 reads (6%) | catalogued as COSV63544079; called by muse, mutect2
- PCDHB11 | c.1137A>C p.G379= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV61310057; called by muse, mutect2
- PCDHGA3 | c.2241G>T p.R747= | Silent (SNP) | VAF 14/126 reads (11%) | called by mutect2, varscan2
- PCSK2 | c.465A>G p.G155= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- PTPRD | c.801A>G p.V267= | Silent (SNP) | VAF 26/298 reads (9%) | called by muse, mutect2
- RAPGEF4 | c.2598C>T p.I866= | Silent (SNP) | VAF 19/249 reads (8%) | catalogued as rs202008176, COSV99910557; called by muse, mutect2
- RIMS4 | c.510C>A p.T170= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- RTN1 | c.1695G>T p.A565= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV50725849; called by muse, mutect2, varscan2
- SELP | c.2034C>T p.L678= | Silent (SNP) | VAF 17/359 reads (5%) | catalogued as rs1425842605, COSV55249966; called by muse, mutect2
- SEMA4B | c.513C>T p.D171= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs746797266; called by muse, mutect2
- SOX1 | c.759G>C p.A253= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- TCF23 | c.192G>T p.G64= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs1392288374; called by muse, mutect2
- TTN | c.12469A>C p.R4157= (on ENST00000591111; = p.R4111= on NM_003319.4) | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- XIRP2 | c.6144A>G p.T2048= (on ENST00000628543; = p.T2223= on NM_152381.6) | Silent (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- ADARB2 | c.1683-63A>C | Intron (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- CSMD3 | c.7885+87G>A | Intron (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- HMGN2P15 | n.94C>G | RNA (SNP) | VAF 24/328 reads (7%) | called by muse, mutect2
- LINC02694 | n.532del | RNA (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- OR2W5 | n.1177C>T | RNA (SNP) | VAF 9/201 reads (4%) | called by muse, mutect2
